Somatic mutation profile of tumor specimen C3N-09075-01 (aliquot CPT0496570010) from CPTAC case C3N-09075, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 58.0 years (21,170 days).
Specimen C3N-09075-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc1c5795-8d49-4933-be14-5598a76bd20c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-09075-31 (Blood Derived Normal), aliquot CPT0496690006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b68436ac-cafb-46a6-9e35-f4efeb3d0402

The open-access MAF lists 124 somatic variants for this specimen: 76 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 42, Intron 4, Nonsense Mutation 4, Splice Site 1, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.1488C>T p.F496= | Splice Region (SNP) | VAF 72/274 reads (26%) | catalogued as rs1564547636, COSV64599360; called by muse, mutect2, varscan2
- ANKRD36C | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.887); catalogued as rs767323942; called by muse, mutect2, varscan2
- ATP1B3 | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1443582378; called by muse, mutect2, varscan2
- CASP9 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 133/351 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61601662; called by muse, mutect2, varscan2
- CPE | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 79/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1221932009; called by muse, mutect2, varscan2
- DUSP8 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 140/570 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs372718516; called by muse, mutect2, varscan2
- ENPP6 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99699144; called by muse, mutect2, varscan2
- FAM220A | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 102/380 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs756102302, COSV100510772; called by muse, varscan2
- FAM47C | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs143434116, COSV100792912, COSV63723682; called by muse, mutect2, varscan2
- FOXN1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 124/538 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as rs1026597581, COSV56884035; called by muse, mutect2, varscan2
- GPATCH8 | c.3572A>G p.H1191R | Missense Mutation (SNP) | VAF 105/465 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs760203513; called by muse, mutect2, varscan2
- GPLD1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs143246933; called by muse, mutect2, varscan2
- HAUS8 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs746189355; called by muse, mutect2, varscan2
- IGHA1 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs750482734; called by muse, mutect2, varscan2
- KCNH5 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604016, COSV59767610; called by muse, mutect2, varscan2
- KCNH7 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100038307; called by muse, mutect2, varscan2
- MUC17 | c.10045A>C p.T3349P | Missense Mutation (SNP) | VAF 124/468 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs766124492; called by muse, mutect2, varscan2
- OR5AC2 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs1204898926, COSV104423234; called by muse, mutect2, varscan2
- PARD3 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100401420; called by muse, mutect2, varscan2
- PCNX2 | c.3946C>T p.H1316Y | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs754079857, COSV50836927; called by muse, mutect2, varscan2
- PITPNM1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 102/495 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1565196013; called by muse, mutect2, varscan2
- PRUNE2 | c.7180C>T p.P2394S | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs761631079; called by muse, mutect2, varscan2
- PTCHD4 | c.2299C>T p.L767F | Missense Mutation (SNP) | VAF 91/445 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs1480539041, COSV104412839; called by muse, mutect2, varscan2
- PYGO1 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 75/327 reads (23%) | catalogued as COSV57349922; called by muse, mutect2, varscan2
- RFTN1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 146/597 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs781778331, COSV61920252; called by muse, mutect2, varscan2
- RIPOR3 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs770915755, COSV99246561; called by muse, mutect2, varscan2
- SGMS1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 109/428 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62371122; called by muse, mutect2, varscan2
- SLC28A2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 70/442 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs867708907; called by muse, mutect2, varscan2
- SMYD4 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59714054; called by muse, mutect2, varscan2
- SNRPA | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 101/435 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV54682160; called by muse, mutect2, varscan2
- TEX2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 125/484 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.758); catalogued as rs782338359, COSV51984638; called by muse, mutect2, varscan2
- TNK1 | c.1888G>A p.V630I (on ENST00000576812 / NM_001251902.2; = p.V625I on NM_003985.5) | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100248058; called by muse, mutect2
- TRAP1 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 103/435 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1265074330; called by muse, mutect2, varscan2
- TTC6 | c.1414G>A p.D472N (on ENST00000267368; = p.D1838N on NM_001310135.3) | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1339409152; called by muse, mutect2, varscan2
- ZNF679 | c.773A>T p.H258L | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV99739443; called by muse, mutect2, varscan2
- ZNF98 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs200329227, COSV63334171; called by muse, mutect2, varscan2
- AARS1 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 93/359 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ADGRB2 | c.4025C>T p.P1342L | Missense Mutation (SNP) | VAF 142/396 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ARHGAP33 | c.983T>G p.V328G | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL7B | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BLNK | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CABLES1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2
- CACNA1E | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCM2L | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 116/460 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.06); called by muse, varscan2
- CNTNAP4 | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 97/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CRISP2 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.10207-1G>A p.X3403_splice | Splice Site (SNP) | VAF 89/228 reads (39%) | called by muse, mutect2, varscan2
- DNAI3 | c.2072T>C p.V691A | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DRD3 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSC2 | c.2277A>C p.Q759H | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- F13A1 | c.80T>A p.L27Q | Missense Mutation (SNP) | VAF 100/476 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by mutect2, varscan2
- FAM9A | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 156/316 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GNA13 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HTR1B | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 116/484 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAG2 | c.3912G>A p.W1304* (on ENST00000636465; = p.W349* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/253 reads (11%) | called by muse, mutect2, varscan2
- KCNE1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 133/392 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- KCNH1 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC75B | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 130/517 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTN1 | c.1270T>G p.L424V | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP153 | c.3797C>T p.T1266I | Missense Mutation (SNP) | VAF 104/531 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- OR5H6 | c.169G>A p.G57R (on ENST00000642105; = p.G41R on NM_001005479.2) | Missense Mutation (SNP) | VAF 110/408 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PHIP | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PHIP | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PSTPIP1 | c.1191G>A p.W397* | Nonsense Mutation (SNP) | VAF 97/368 reads (26%) | called by muse, mutect2, varscan2
- RYR1 | c.13921G>A p.E4641K | Missense Mutation (SNP) | VAF 117/523 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SDSL | c.122T>G p.V41G | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- SEMA3B | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SLC22A24 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A4 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 125/497 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLCO1B3 | c.1395T>G p.C465W | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPDYE3 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 32/463 reads (7%) | SIFT deleterious (0.05); called by muse, varscan2
- TBC1D2B | c.659T>A p.L220* | Nonsense Mutation (SNP) | VAF 59/308 reads (19%) | called by muse, mutect2, varscan2
- TICRR | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 98/385 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- TRPC5 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 126/267 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- WDR37 | c.1000A>C p.T334P | Missense Mutation (SNP) | VAF 104/448 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- ZMYND15 | c.1754A>T p.K585I (on ENST00000433935 / NM_001136046.3; = p.K546I on NM_032265.2) | Missense Mutation (SNP) | VAF 141/510 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY10 | c.1032C>T p.F344= | Silent (SNP) | VAF 58/259 reads (22%) | catalogued as COSV63241601; called by muse, mutect2, varscan2
- APBB3 | c.1407C>T p.V469= (on ENST00000357560 / NM_133173.2; = p.V476= on NM_006051.3) | Silent (SNP) | VAF 140/504 reads (28%) | catalogued as COSV60365896; called by muse, mutect2, varscan2
- CCP110 | c.2295A>T p.G765= | Silent (SNP) | VAF 115/452 reads (25%) | called by muse, mutect2, varscan2
- CHGA | c.1227C>G p.L409= | Silent (SNP) | VAF 117/441 reads (27%) | called by muse, varscan2
- CSMD3 | c.9747C>T p.F3249= (on ENST00000297405 / NM_001363185.1; = p.F3080= on NM_052900.3) | Silent (SNP) | VAF 95/462 reads (21%) | catalogued as rs61754530, COSV52091126; called by muse, mutect2, varscan2
- CYP4A22 | c.1050G>A p.E350= | Silent (SNP) | VAF 135/483 reads (28%) | called by muse, mutect2, varscan2
- ETV3 | c.1176C>T p.S392= | Silent (SNP) | VAF 119/515 reads (23%) | catalogued as rs1025456826; called by muse, mutect2, varscan2
- GRHL2 | c.1137C>T p.S379= | Silent (SNP) | VAF 22/400 reads (6%) | catalogued as rs768448448, COSV52549231; called by muse, mutect2
- H4C5 | c.81C>T p.I27= | Silent (SNP) | VAF 113/515 reads (22%) | catalogued as COSV63486767; called by muse, mutect2, varscan2
- JAKMIP1 | c.2328C>T p.F776= | Silent (SNP) | VAF 136/491 reads (28%) | catalogued as rs898744590; called by muse, mutect2, varscan2
- KLHL38 | c.180G>A p.R60= | Silent (SNP) | VAF 99/470 reads (21%) | catalogued as rs1364254968; called by muse, mutect2, varscan2
- KLRC1 | c.426G>A p.E142= | Silent (SNP) | VAF 157/414 reads (38%) | catalogued as COSV100760703, COSV61725373; called by muse, mutect2, varscan2
- LRSAM1 | c.57G>A p.E19= | Silent (SNP) | VAF 92/325 reads (28%) | catalogued as COSV55942060; called by muse, mutect2, varscan2
- LRTM1 | c.669G>A p.R223= | Silent (SNP) | VAF 110/481 reads (23%) | catalogued as COSV55546789; called by muse, mutect2, varscan2
- MAGEA6 | c.750C>T p.F250= | Silent (SNP) | VAF 157/308 reads (51%) | catalogued as rs782585932, COSV61448617, COSV61449289; called by muse, mutect2, varscan2
- MESP1 | c.738C>T p.D246= | Silent (SNP) | VAF 92/388 reads (24%) | catalogued as rs762940284; called by muse, mutect2, varscan2
- MUC6 | c.3171C>T p.A1057= | Silent (SNP) | VAF 32/634 reads (5%) | catalogued as rs773367939; called by muse, mutect2
- MYH1 | c.528G>A p.L176= | Silent (SNP) | VAF 70/229 reads (31%) | catalogued as COSV56844520; called by muse, mutect2, varscan2
- MYO1F | c.78C>T p.P26= | Silent (SNP) | VAF 117/508 reads (23%) | called by muse, mutect2, varscan2
- OPRD1 | c.312C>T p.F104= | Silent (SNP) | VAF 97/317 reads (31%) | called by muse, mutect2, varscan2
- OR51B6 | c.546C>T p.V182= | Silent (SNP) | VAF 113/354 reads (32%) | called by muse, mutect2, varscan2
- OR6C75 | c.938G>A p.*313= | Silent (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- PAN2 | c.510C>T p.L170= | Silent (SNP) | VAF 73/292 reads (25%) | catalogued as rs200635843, COSV99228186; called by muse, mutect2, varscan2
- PAQR8 | c.714T>A p.A238= | Silent (SNP) | VAF 135/437 reads (31%) | called by muse, mutect2, varscan2
- PDYN | c.264G>A p.G88= | Silent (SNP) | VAF 127/485 reads (26%) | called by muse, mutect2, varscan2
- PFKP | c.1141C>A p.R381= | Silent (SNP) | VAF 73/349 reads (21%) | catalogued as rs575893132, COSV66897806; called by muse, mutect2, varscan2
- POU2F3 | c.1146C>T p.S382= | Silent (SNP) | VAF 82/319 reads (26%) | catalogued as rs1225940501; called by muse, mutect2, varscan2
- PRKDC | c.7875C>T p.L2625= | Silent (SNP) | VAF 98/448 reads (22%) | called by muse, mutect2, varscan2
- PRSS58 | c.321G>A p.L107= | Silent (SNP) | VAF 244/728 reads (34%) | called by muse, mutect2, varscan2
- PSG9 | c.732C>T p.I244= | Silent (SNP) | VAF 130/302 reads (43%) | catalogued as rs1376014026; called by muse, mutect2, varscan2
- RFTN1 | c.240G>A p.A80= | Silent (SNP) | VAF 146/591 reads (25%) | catalogued as rs200870463; called by muse, mutect2, varscan2
- RSPH6A | c.2007C>T p.Y669= | Silent (SNP) | VAF 102/443 reads (23%) | called by muse, varscan2
- SCEL | c.714C>T p.I238= | Silent (SNP) | VAF 78/282 reads (28%) | catalogued as COSV62994233; called by muse, mutect2, varscan2
- SCN11A | c.3570C>T p.L1190= | Silent (SNP) | VAF 74/273 reads (27%) | catalogued as rs267599812; called by muse, mutect2, varscan2
- SETD5 | c.306C>T p.F102= | Silent (SNP) | VAF 78/315 reads (25%) | called by muse, mutect2, varscan2
- SLC39A8 | c.732A>G p.Q244= | Silent (SNP) | VAF 90/362 reads (25%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.282G>A p.P94= | Silent (SNP) | VAF 56/265 reads (21%) | catalogued as rs762672865, COSV53932888, COSV99680650; called by muse, mutect2, varscan2
- SOX30 | c.684G>A p.A228= | Silent (SNP) | VAF 152/575 reads (26%) | catalogued as COSV53939335; called by muse, mutect2, varscan2
- ST3GAL4 | c.909C>T p.S303= (on ENST00000392669 / NM_001254758.1; = p.S299= on NM_006278.3) | Silent (SNP) | VAF 79/278 reads (28%) | catalogued as rs1320544407; called by muse, mutect2, varscan2
- TAOK2 | c.3519C>T p.P1173= | Silent (SNP) | VAF 139/615 reads (23%) | catalogued as rs765388827; called by muse, mutect2, varscan2
- TMEM232 | c.1326G>A p.V442= | Silent (SNP) | VAF 83/331 reads (25%) | catalogued as COSV70267872; called by muse, mutect2, varscan2
- XIRP2 | c.7848G>A p.K2616= (on ENST00000628543; = p.K2791= on NM_152381.6) | Silent (SNP) | VAF 96/326 reads (29%) | called by muse, mutect2, varscan2
- CD72 | c.262+90C>T | Intron (SNP) | VAF 117/435 reads (27%) | called by muse, mutect2, varscan2
- EPN1 | c.-101-820G>C | Intron (SNP) | VAF 90/260 reads (35%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-30295G>A | Intron (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- MITF | c.579+308G>A | Intron (SNP) | VAF 80/386 reads (21%) | called by muse, mutect2, varscan2
- PTPRT | c.*6104G>A | 3'UTR (SNP) | VAF 70/315 reads (22%) | called by muse, mutect2, varscan2
- REXO1L1P | n.730C>T | RNA (SNP) | VAF 28/888 reads (3%) | catalogued as rs1282696128; called by muse, mutect2
